TCGA case TCGA-FU-A770 — Cervical Squamous Cell Carcinoma and Endocervical Adenocarcinoma (TCGA-CESC)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of The Cancer Genome Atlas (TCGA). Disease type: Adenomas and Adenocarcinomas; Primary site: Cervix uteri; Tissue source site: International Genomics Consortium. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/128fd280-9a04-4038-9269-9a945b9a4dc9

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Country of residence at enrollment: United States; Age at index: 33 years; Vital status: Alive.

Diagnoses (1)
1. Adenocarcinoma, endocervical type: ICD-O-3 morphology code: 8384/3; ICD-10 code: C53.9; Tissue or organ of origin: Cervix uteri; Site of resection or biopsy: Cervix uteri; Classification of tumor: primary; Age at diagnosis: 33.5 years (12,248 days); Year of diagnosis: 2013; Method of diagnosis: Dilation and Curettage Procedure; AJCC pathologic T: T2a2; AJCC pathologic N: N1; AJCC pathologic M: MX; FIGO stage: Stage IIIB; FIGO staging edition year: 2009; Tumor grade: G2; Prior malignancy: no; Synchronous malignancy: No; Prior treatment: No; Days to last follow up: 34 days.
   Pathology details: Consistent pathology review: Yes; Lymph nodes positive: 1; Lymph nodes tested: 10; Lymphatic invasion present: No.
   Pathology details: Lymph node involved site: Pelvis, NOS.

Follow-up (2 entries)
- Day 30 (preoperative): ECOG performance status: 1.
- Days to follow up: 34 days; Disease response: Tumor Free.

Other clinical attributes
- Timepoint category: Initial Diagnosis; Menopause status: Premenopausal; Pregnant at diagnosis: No.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Induced Abortion.
- Timepoint category: Prior to Diagnosis; Hormonal contraceptive use: Former User; Hysterectomy type: Radical Hysterectomy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Ectopic Pregnancy.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Live Birth.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 0; Pregnancy outcome: Stillbirth.
- Timepoint category: Initial Diagnosis; Weight: 67 kg; Height: 175 cm; BMI: 21.9.
- Timepoint category: Prior to Diagnosis; Number of pregnancies: 1; Pregnancy outcome: Miscarriage.

Exposures
- Exposure type: Tobacco; Tobacco smoking status: Current Smoker; Pack years smoked: 7; Age at onset: 16.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample TCGA-FU-A770-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT; Initial weight: 40 mg.
  Slide TCGA-FU-A770-01A-01-TS1: Section location: Top; Percent tumor cells: 80; Percent tumor nuclei: 80; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 20; Percent lymphocyte infiltration: 40; Percent monocyte infiltration: 20; Percent neutrophil infiltration: 20.
- Sample TCGA-FU-A770-01Z: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE; Days to sample procurement: 0 days.
- Sample TCGA-FU-A770-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: Yes; Retrospective collection: No; Menopause status: Pre (<6 months since LMP AND no prior bilateral ovariectomy AND not on estrogen replacement); History neoadjuvant treatment: No; Tumor status: Tumor free; Live birth pregnancy count: 1; Pregnancies count miscarriage: 1; Pregnancies count induced abortion: 0; Pregnancies count ectopic: 0; Pregnancies count stillbirth: 0; Total pregnancy count: 2; Tobacco smoking history indicator: 2; Submitted tumor site: Cervical; Histologic diagnosis: Endocervical Adenocarcinoma of the Usual Type; Method initial path diagnosis: Other method, specify:; Method initial path diagnosis other: D&C; Pelvic extension comment: Tumor extends 1.0cm into 1.3 cm thick cervical/lower uterine segment wall; Lymph nodes examined: Yes; Lymphovascular invasion: Absent; Corpus involvement: Absent; New tumor event diagnosis indicator: No.
- Lymph node location positive pathology names: Pos lymph node location: Pelvic (external iliac, internal iliac, obturator).

Curated follow-up endpoints (TCGA Pan-Cancer Clinical Data Resource, Liu et al., Cell 2018; times are days from initial pathologic diagnosis to the event or to last contact): overall survival: no event (censored), 34 days; disease-specific survival: no event (censored), 34 days; progression-free interval: no event (censored), 34 days.

Tumor purity and ploidy (ABSOLUTE, TCGA Pan-Cancer Atlas; aliquot TCGA-FU-A770-01A-11D-A33N-01): tumor purity 0.61, ploidy 1.91, whole-genome doublings 0.
